Surgical pathology report (de-identified scan), TCGA case TCGA-06-0173, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0173-01A (Primary Tumor).

PATHOLOGICAL DIAGNOSIS:

BRAIN BIOPSY: GLIOBLASTOMA MULTIFORME. (MIB-1: 30%)

Operation/Specimen: Brain tumor.

Clinical History and Pre-Op Dx: FS.

GROSS PATHOLOGY: Multiple 0.6-1.0 cm. tissue fragments.

INTRAOPERATIVE CONSULTATION, Frozen section diagnosis: Glioma.

CASSETTES: Glioma in cassette 1, remaining tissue in cassette 2, X1.

MICROSCOPIC: Sections show a high grade glioma with the following findings: High cellular density, cytological pleomorphism, mitotic figures, vascular proliferation with thrombosis and areas of necrosis. The features are consistent with glioblastoma multiforme.

Source: NCI Genomic Data Commons file ca618efd-7af9-4853-baba-c1a723084498 (TCGA-06-0173.623DE96F-C53A-43D8-B0B1-DE2D8A9F7A51.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).